Gene-level copy-number profile of tumor specimen ALCH-AE4S-TTR1-A from ALCHEMIST case ALCH-AE4S, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.7 years (21,090 days).
Specimen ALCH-AE4S-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 90d01760-84f8-4d44-8a03-b0a2f6366de1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AE4S-NB1-B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/7a89facc-8cad-4426-bf4e-c3969fec1743

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 529; copy number 1: 15,065; copy number 2: 40,056; copy number 3: 3,031; copy number 4: 211; copy number 5: 11; copy number 8: 1; copy number 10: 1.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:43,978,943–44,031,467, 3 genes (within-gene range 0–2): B4GALT2, CCDC24, SLC6A9.
- chr4:25,529,177–25,619,468, 2 genes: AC105290.1, RNU7-126P.
- chr8:7,778,591–7,781,413, 1 gene: PRR23D2.
- chr8:8,019,429–8,024,652, 1 gene: FAM90A24P.
- chr9:6,639,139–6,727,438, 8 genes (within-gene range 0–1): RPL23AP57, AL162411.1, RN7SL123P, RPS3AP54, RNF2P1, RPL35AP20, LINC02851, AL354707.1.
- chr11:3,029,009–3,041,260, 1 gene (within-gene range 0–1): CARS1-AS1.
- chr19:33,795,933–33,815,763, 1 gene: KCTD15.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 13 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:108,226,015–108,534,196, 11 genes, copy number 5: SETD6P1, SULT1C3, WASF1P1, SULT1C2, SULT1C2P2, SULT1C2P1, GMCL1P2, SULT1C4, SMIM12P1, GCC2, GCC2-AS1.
- chr14:105,583,731–105,588,395, 1 gene, copy number 8: IGHA2.
- chr14:105,620,506–105,626,066, 1 gene, copy number 10 (within-gene range 3–10): IGHG4.

Autosomal genes at a single copy (total copy number 1): 12,721. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
